Somatic mutation profile of tumor specimen TCGA-KK-A8IB-01A (aliquot TCGA-KK-A8IB-01A-11D-A364-08) from TCGA case TCGA-KK-A8IB, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.8 years (24,041 days).
Specimen TCGA-KK-A8IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66df6399-faaa-48ae-ad50-b226a9dc20c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IB-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IB-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9612025-9bac-41f5-9af5-0ebce5a6a242

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.758T>A p.M253K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51643604, COSV51643636, COSV51645087; called by muse, mutect2
- BDKRB1 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53706703; called by muse, mutect2, varscan2
- CHL1 | c.2926C>A p.P976T (on ENST00000397491 / NM_001253387.1; = p.P992T on NM_006614.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99850325; called by muse, mutect2, varscan2
- DNAH17 | c.8891C>T p.A2964V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760238543, COSV67756311; called by muse, mutect2
- DYNC1H1 | c.7480C>G p.L2494V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as COSV100794569, COSV64135019; called by muse, mutect2, varscan2
- FAM126B | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as rs762955857, COSV53771892, COSV99627441; called by muse, mutect2, varscan2
- FLG | c.5995T>C p.S1999P | Missense Mutation (SNP) | VAF 101/653 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.161); catalogued as COSV100910757; called by muse, mutect2, varscan2
- FOLR3 | c.603C>G p.N201K | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.152); catalogued as COSV100281743; called by muse, mutect2
- GALNT15 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV60220224; called by muse, mutect2, varscan2
- HCN1 | c.293T>G p.F98C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100298960; called by muse, mutect2, varscan2
- HIKESHI | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as COSV99563285; called by muse, mutect2
- KCNK17 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100950093; called by muse, mutect2, varscan2
- KIRREL3 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs119462978, CM086843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.15053C>T p.T5018I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as rs1184465070, COSV99978282; called by muse, mutect2, varscan2
- KMT2D | c.14759C>G p.P4920R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99978284; called by muse, mutect2, varscan2
- KRTAP5-1 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 11/93 reads (12%) | PolyPhen benign (0.107); catalogued as rs1404765544, COSV101192871, COSV66298635; called by muse, mutect2, varscan2
- LTBP2 | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99999847; called by muse, mutect2, varscan2
- NEXMIF | c.574A>T p.N192Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV99279880; called by muse, mutect2, varscan2
- OPRM1 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs759812386, COSV57674714, COSV57684010; called by muse, mutect2, varscan2
- PLCB4 | c.1161T>G p.D387E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV53810678, COSV99594585; called by muse, varscan2
- PRKAA2 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV100982760; called by muse, mutect2
- RYR1 | c.5464G>A p.G1822S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.588); catalogued as rs1169294876, COSV100614822, COSV62113655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STARD13 | c.1301G>A p.G434D (on ENST00000336934 / NM_001243476.3; = p.G316D on NM_052851.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV99715527; called by muse, mutect2
- SYNE1 | c.10655T>A p.V3552E (on ENST00000367255 / NM_182961.4; = p.V3559E on NM_033071.3) | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV99555572; called by muse, mutect2
- THEMIS2 | c.1907T>G p.L636R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100197923; called by muse, mutect2, varscan2
- TRIP12 | c.4123_4124del p.E1375Ifs*4 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | catalogued as rs771838498; called by pindel, varscan2
- UBXN2B | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs1267451631, COSV101275570; called by mutect2, varscan2
- VPS35 | c.2274A>C p.E758D | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100140490; called by muse, mutect2, varscan2
- ZBTB34 | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100043575; called by muse, mutect2
- ZC3H13 | c.3950A>T p.D1317V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99667634; called by muse, varscan2
- ZNF804A | c.1535A>C p.E512A | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100166697; called by mutect2, varscan2
- DSEL | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- TBC1D32 | c.961_963del p.T321del | In Frame Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel, varscan2
- ANPEP | c.867C>T p.Y289= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs1340399275, COSV100262702, COSV55589822; called by muse, mutect2, varscan2
- ASB15 | c.1074T>C p.V358= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV99306270; called by muse, mutect2, varscan2
- CHD1 | c.3033A>C p.V1011= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99399159; called by muse, mutect2, varscan2
- FAM133A | c.438G>A p.T146= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1277479941, COSV59078565; called by muse, mutect2, varscan2
- IGSF10 | c.2490T>C p.D830= | Silent (SNP) | VAF 6/133 reads (5%) | catalogued as COSV56786014; called by muse, mutect2
- LMAN1L | c.1116C>T p.S372= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100547595; called by muse, mutect2, varscan2
- MORN3 | c.21A>G p.P7= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV100804441; called by muse, mutect2
- OR10T2 | c.61C>T p.L21= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100554840; called by muse, mutect2, varscan2
- PCDHGA9 | c.735G>T p.R245= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99532585; called by muse, mutect2, varscan2
- RNF144A | c.858C>T p.D286= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs756316410, COSV57983044; called by muse, mutect2
- TM7SF3 | c.315G>A p.Q105= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100544672; called by muse, mutect2, varscan2
- ZRANB1 | c.1704A>G p.E568= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100456195; called by muse, mutect2, varscan2
- KLHDC9 | c.688-15T>A | Intron (SNP) | VAF 20/378 reads (5%) | catalogued as COSV100919647; called by muse, mutect2
- POLA1 | c.2947-21442T>C | Intron (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
